Surgical pathology report (de-identified scan), TCGA case TCGA-ET-A2N4, project TCGA-THCA (Thyroid Carcinoma), tissue source site Johns Hopkins, specimen TCGA-ET-A2N4-01A (Primary Tumor).

Dual, Synchronous Primary / Mixed		☒

SPECIMEN TAKEN:

FINAL DIAGNOSIS -----

THYROID (TOTAL THYROIDECTOMY):

1CD-0-3

carcinoma, papillary, follicular variant 8340/3

TUMOR SITE:

Right lobe, isthmus, left lobe

Site: thyroid, NOS C73.9

hw
8/18/11

HISTOLOGIC TYPE:

Papillary carcinoma, follicular variant with angioinvasion

TUMOR SIZE:

Greatest dimension: 4.5 cm (entirety of the left lobe, extending into isthmus)

FOCALITY:

Multifocal

LYMPH NODES:

All 2 nodes negative for tumor

EXTENT OF INVASION

PRIMARY TUMOR:

pT3: Tumor >4 cm, limited to thyroid or with minimal extrathyroidal extension

REGIONAL LYMPH NODES:

pNO: No regional lymph node metastasis

DISTANT METASTASIS:

pMX: Cannot be assessed

MARGINS:

Margins are uninvolved

Distance of invasive carcinoma from nearest margin: <1 mm (anterior, posterior)

VENOUS/LYMPHATIC INVASION:

Present

ADDITIONAL PATHOLOGIC FINDINGS:

Nodular hyperplasia with cystic degeneration

NOTE: This case was shown at the

Source: NCI Genomic Data Commons file 3c83f67f-42a6-4cc9-b54b-5e44f1afebb2 (TCGA-ET-A2N4.76F3BFF3-8538-4736-85AB-2BEE2629F3BE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).